Surgical pathology report (de-identified scan), TCGA case TCGA-41-4097, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-4097-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Right temporal lobe mass
- B. Right temporal lobe mass -
- C. Right temporal lobe mass
- D. Right temporal lobe mass

CLINICAL NOTES

PRE-OP DIAGNOSIS: Brain mass

FROZEN SECTION DIAGNOSIS

- A - Brain tissue with focal hypercellularity; no definite malignancy present.
- C - Glioblastoma multiforme.

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "right temporal lobe mass." It consists of two fragments of soft tan tissue. In aggregate these measure 0.9 x 0.4 x 0.3 cm. A touch preparation is made and the entire specimen is submitted in one block for frozen section.

B. Specimen taken for tissue procurement.

C. Part C is received fresh for frozen section labeled "right temporal lobe mass." It consists of several fragments of soft tan tissue measuring 7 x 6 x 3 mm. in aggregate.

A

touch preparation is made and the entire specimen is submitted in one block for frozen section.

D. Received in formalin, labeled "right temporal brain lobe mass" are three pink-tan irregular rubbery tissue fragments which average 0.7 cm. in greatest dimension each. No orientation of specimens are given. The specimens are entirely submitted in one cassette. AS-1.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

A. Microscopic examination performed.

C. D. This right temporal lobe mass is a high grade astrocytic neoplasm composed of a dense population of markedly pleomorphic large cells with readily identifiable mitotic figures. Pseudopalisading around broad areas of necrosis is noted. There is focal spindle cell component to the tumor and focal vascular proliferation. The features are compatible with glioblastoma multiforme.

4x3, 14x2

DIAGNOSIS

A. Right temporal lobe mass, biopsy - Mildly gliotic brain tissue, no definite tumor present.

B. Right temporal lobe mass - This specimen has been sent directly for tissue procurement.

C, D. Right temporal lobe mass, excision - Glioblastoma multiforme.

--- End Of Report---

Source: NCI Genomic Data Commons file 6d101159-cf8c-4beb-8351-d5c7a42367e6 (TCGA-41-4097.38E71ADA-A221-41FD-9283-5750413305B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).